Somatic mutation profile of tumor specimen 0DIPL9 from CCDI case PBBWAR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 5.7 years (2,097 days).
Specimen 0DIPL9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 294578cb-d058-4000-b064-2fab9aade443.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIPKS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7aa87cef-c496-4f2b-844e-26c4d9299cf8

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FPGT-TNNI3K | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 408/1820 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs79936844, COSV58559305; called by muse, varscan2
- MORC4 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 208/824 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs750951386, COSV55240956; called by muse, varscan2
- MKS1 | c.262-89T>C | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- SLC15A3 | c.997-98C>G | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, varscan2
